Somatic mutation profile of tumor specimen TCGA-2A-A8VX-01A (aliquot TCGA-2A-A8VX-01A-11D-A377-08) from TCGA case TCGA-2A-A8VX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.9 years (25,904 days).
Specimen TCGA-2A-A8VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6235b08a-0e1c-40bf-b4f2-06db854d07e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8VX-10A (Blood Derived Normal), aliquot TCGA-2A-A8VX-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b0dee3-8d64-4980-9037-a7aa5664b159

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.761_766del p.F254_N256delinsY | In Frame Del (DEL) | VAF 14/26 reads (54%) | hotspot (GDC flag); catalogued as COSV51644065; called by mutect2, pindel, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs281875187, CM122549, CM122554, COSV61813999, COSV61814572; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARID1A | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV61376637; called by muse, mutect2, varscan2
- CALB2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs1375850883, COSV56940903; called by muse, mutect2, varscan2
- CCR2 | c.48C>A p.S16R | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV99432079; called by muse, mutect2, varscan2
- CDH12 | c.2170A>G p.N724D | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV101201721; called by muse, mutect2, varscan2
- CNR2 | c.821G>C p.S274T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100991250; called by muse, mutect2, varscan2
- FCRL3 | c.961T>C p.S321P | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63845279; called by muse, mutect2, varscan2
- FHOD3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371092594, COSV57178840; called by muse, mutect2, varscan2
- GADL1 | c.731+2T>C p.X244_splice | Splice Site (SNP) | VAF 62/141 reads (44%) | catalogued as COSV99243908; called by muse, mutect2, varscan2
- LCMT2 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99979929; called by muse, mutect2, varscan2
- MLX | c.878T>G p.L293W | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99518760; called by muse, mutect2, varscan2
- MYLK2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV101044671; called by muse, mutect2, varscan2
- MZT2B | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99919691; called by muse, mutect2, varscan2
- PCDHGC4 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.541); catalogued as rs747722740, COSV99338413; called by muse, mutect2, varscan2
- SERPINB10 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV99448828; called by muse, mutect2, varscan2
- SERPINI2 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1343580668, COSV99247615; called by muse, mutect2, varscan2
- SIRPA | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs758551564, COSV100605047; called by muse, mutect2, varscan2
- SLC16A4 | c.239T>G p.I80S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as COSV100872910; called by muse, mutect2, varscan2
- SLC25A32 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52570129, COSV99884231; called by muse, mutect2, varscan2
- SLC26A4 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99706626; called by muse, mutect2, varscan2
- SLC45A2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1352999116, CM040234, COSV56871908; called by muse, mutect2, varscan2
- SMG7 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as COSV100750108; called by muse, mutect2, varscan2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 54/71 reads (76%) | catalogued as rs761320003; called by mutect2, varscan2
- UTP20 | c.7525A>G p.K2509E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV55383770; called by muse, mutect2, varscan2
- ARID2 | c.5294_5297del p.T1765Nfs*5 | Frame Shift Del (DEL) | VAF 47/107 reads (44%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.5392_5408del p.F1798Qfs*3 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- FBXW10 | c.1263C>T p.S421= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs779844273, COSV100111247; called by muse, mutect2, varscan2
- NAA25 | c.153G>A p.K51= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs898970791, COSV99927324; called by muse, mutect2, varscan2
- RPS2 | c.135C>T p.G45= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV99238707; called by muse, mutect2, varscan2
- TAGAP | c.1614C>T p.H538= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100487294; called by muse, mutect2
